Gene-level copy-number profile of tumor specimen TCGA-13-0795-01A from TCGA case TCGA-13-0795, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 66.8 years (24,403 days).
Specimen TCGA-13-0795-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.797c5f18-5c06-4bf6-ae32-63b9a2a27150.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0795-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b370448f-6b6b-4e38-9de0-d3fbce2702fe

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,073; copy number 2: 11,448; copy number 3: 14,520; copy number 4: 18,415; copy number 5: 6,103; copy number 6: 4,510; copy number 7: 2,401; copy number 8: 825; copy number 9: 251; copy number 10: 143; copy number 12: 102; copy number 13: 5; copy number 18: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0795-01A-01D-0356-01): tumor purity 0.48, ploidy 3.74, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 443 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:65,302,522–67,467,308, 9 genes, copy number 9: AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208.
- chr7:31,751,179–32,428,131, 1 gene, copy number 9 (within-gene range 5–9): PDE1C.
- chr7:32,427,901–33,109,404, 24 genes, copy number 9: AC018637.1, AC018641.1, SLC25A5P5, LSM5, AVL9, DPY19L1P1, ZNRF2P1, MIR550A2, MIR550B2, AC018645.3, LINC00997, AC018645.1, AC018645.2, DPY19L1P2, AC018648.1, KBTBD2, RP9P, AC083863.1, FKBP9, RNU6-388P, NT5C3A, RPS29P14, RN7SL505P, RP9.
- chr12:564,296–4,774,184, 104 genes, copy number 10 (within-gene range 4–10) (broad region; genes not listed).
- chr12:25,779,287–32,396,147, 152 genes, copy number 9 (broad region; genes not listed).
- chr12:32,477,382–32,477,471, 1 gene, copy number 9: RNU6-494P.
- chr16:34,266,041–35,912,516, 86 genes, copy number 9–12 (broad region; genes not listed).
- chr18:27,225,742–27,247,188, 1 gene, copy number 9: LINC01908.
- chr18:27,343,252–27,401,910, 3 genes, copy number 9: AC021382.1, UBA52P9, AC068408.1.
- chr19:27,638,483–30,228,715, 62 genes, copy number 10–18 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
